Surgical pathology report (de-identified scan), TCGA case TCGA-06-5856, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5856-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

CLINICAL HISTORY

The patient is a [REDACTED] who has a large lesion involving left frontal, temporal, insular and basal ganglia regions, partially hemorrhagic, enhancing, and encasing internal carotid artery and left optic chiasm. There is marked mass effect with herniations.

OPERATIVE DIAGNOSES

Brain tumor

Operation/Specimen: A: Brain tumor, biopsy
B: Brain tumor, extra axial, biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, left cerebral lesion, biopsy and excision:
Glioblastoma (WHO
Grade IV) (see comment).

COMMENT

Permanent sections confirm the frozen section diagnosis. Sections show a highly cellular and moderately pleomorphic glioma demonstrating mitotic figures, vascular proliferation and necrosis. Immunohistochemical stains show that the tumor cells are diffusely GFAP positive. Synaptophysin highlights the neuropil background and occasional tumor cells. CD3, CD4 and CD34 stain rare to occasional cells. The Ki-67 labeling index is up to approximately 50%. Positive and negative controls show appropriate immunoreactivity.
Electronically Signed Out

PROCEDURES/ADDENDA

[page 2 of 3]
MGMT Promoter Methylation

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain tumor, biopsy: Glioma, high histological grade (C/W glioblastoma).

[page 3 of 3]
Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED] Senior Staff Pathologist

GROSS DESCRIPTION

A.

"Brain tumor," received fresh, two fragments, 0.5 cm. Soft, greyish-pink. In total, A1.

B. Brain tumor, extra axial, biopsy: CONTAINER LABEL: extraaxial brain tumor

FIXATIVE: fresh

GENERAL: Received is a pink-tan fragment of soft tissue, measuring 0.6 x 0.5

x0.5 cm.

SECTIONS: 1, NS, bisected mid, [REDACTED]

ICD-9(s):

239.6 239.6

Histo Data

Part A: Brain tumor, biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
mCD3-DA x 1	1	[REDACTED]	
CD4-NO x 1	1	[REDACTED]	
mGFAP-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
MGMT-curls x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
Rct 1 H/E x 1	1	[REDACTED]	
Synap-DA x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	

Part B: Brain tumor, extra axial, biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	

Source: NCI Genomic Data Commons file ef60dfea-5a40-44d5-98b4-19ac1a07d4b8 (TCGA-06-5856.7BBECEF6-9B0C-43B8-BE9B-55821F9AC49B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).